Somatic mutation profile of tumor specimen 0DVPOI from CCDI case PBCKHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Meningioma, malignant; Tissue or organ of origin: Cerebral meninges; Age at diagnosis: 9.7 years (3,549 days).
Specimen 0DVPOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a8fdfd5-8252-4556-8819-603dd0a4e7f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPOZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b158f9b0-5edd-449e-8672-b411fb29d8e7

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASMTL | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 162/1055 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- RAB8A | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 111/780 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); called by muse, varscan2
- DMKN | c.612T>C p.F204= | Silent (SNP) | VAF 23/236 reads (10%) | catalogued as COSV60087603; called by muse, varscan2
- PSPN | c.27C>T p.G9= | Silent (SNP) | VAF 102/381 reads (27%) | called by muse, varscan2
